Somatic mutation profile of tumor specimen TARGET-30-PAUZSB-01A (aliquot TARGET-30-PAUZSB-01A-01D) from TARGET case TARGET-30-PAUZSB, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.4 years (859 days).
Specimen TARGET-30-PAUZSB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56f4c5bb-1545-4e41-ad99-36cd8405b363.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUZSB-10A (Blood Derived Normal), aliquot TARGET-30-PAUZSB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e8039e1-8a38-4d9c-be1c-bb41427d76fd

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRC | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV61422308; called by muse, mutect2, varscan2
- ANKRD30A | c.1658C>A p.P553Q (on ENST00000611781; = p.P497Q on NM_052997.2) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
